Gene-level copy-number profile of tumor specimen TCGA-DD-A73G-01A from TCGA case TCGA-DD-A73G, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 73.8 years (26,949 days).
Specimen TCGA-DD-A73G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.b59f641d-7c1a-4ce1-bf2c-5dc30feb83e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A73G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6f856a4-89c4-49fd-9d27-d14771689531

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,233; copy number 2: 4,598; copy number 3: 23,662; copy number 4: 23,001; copy number 5: 4,912; copy number 6: 2,155; copy number 7: 247; copy number 8: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A73G-01A-22D-A32F-01): tumor purity 0.58, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 259 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,044,883–199,080,975, 43 genes, copy number 7: LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1, AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1.
- chr1:223,856,579–225,803,448, 40 genes, copy number 7: PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, AL391811.1, DNAH14, LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3.
- chr1:234,527,887–237,014,200, 76 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:237,120,807–237,121,109, 1 gene, copy number 7: RN7SKP195.
- chr8:99,013,266–99,877,580, 1 gene, copy number 7 (within-gene range 5–7): VPS13B.
- chr8:99,233,048–102,504,137, 82 genes, copy number 7 (broad region; genes not listed).
- chr8:126,474,189–127,419,050, 12 genes, copy number 8 (within-gene range 5–8): AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1.
- chr11:11,781,971–11,961,887, 4 genes, copy number 7 (within-gene range 4–7): AC104383.1, MIR8070, USP47, H3P33.

Autosomal genes at a single copy (total copy number 1): 1,233. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
